Somatic mutation profile of tumor specimen TCGA-EJ-5495-01A (aliquot TCGA-EJ-5495-01A-01D-1576-08) from TCGA case TCGA-EJ-5495, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acinar cell carcinoma; Tissue or organ of origin: Prostate gland; Age at diagnosis: 68.2 years (24,904 days).
Specimen TCGA-EJ-5495-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4ecdb302-eb35-4e07-9616-5394cbd8f05d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EJ-5495-10A (Blood Derived Normal), aliquot TCGA-EJ-5495-10A-01D-1577-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b8d4f893-6ca0-4b24-8a14-8d512b2a3587

The open-access MAF lists 78 somatic variants for this specimen: 56 protein-altering or splice-affecting, 12 silent, 10 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 43, Silent 12, RNA 5, Frame Shift Del 4, Splice Site 3, Nonsense Mutation 3, 5'Flank 2, 3'Flank 2, In Frame Del 1, Frame Shift Ins 1, Intron 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRCA2 | c.2175dup p.V726Sfs*25 | Frame Shift Ins (INS) | VAF 24/111 reads (22%) | catalogued as rs276174819; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- ANKRD13B | c.212G>A p.G71D | Missense Mutation (SNP) | VAF 16/99 reads (16%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.501); catalogued as COSV67473994; called by muse, mutect2, varscan2
- APOL1 | c.491G>T p.G164V | Missense Mutation (SNP) | VAF 40/262 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.396); catalogued as COSV59869243; called by muse, mutect2, varscan2
- ARHGEF10 | c.1751G>A p.G584D (on ENST00000398564; = p.G559D on NM_014629.4) | Missense Mutation (SNP) | VAF 49/297 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV50655255; called by muse, mutect2, varscan2
- ASH1L | c.4403G>T p.S1468I | Missense Mutation (SNP) | VAF 37/225 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.001); catalogued as COSV64209264; called by muse, mutect2, varscan2
- ATP1A3 | c.208A>G p.K70E (on ENST00000545399 / NM_001256214.2; = p.K57E on NM_152296.5) | Missense Mutation (SNP) | VAF 21/139 reads (15%) | SIFT tolerated (0.54); PolyPhen benign (0.001); catalogued as COSV57488383; called by muse, mutect2, varscan2
- BICRA | c.63C>A p.D21E | Missense Mutation (SNP) | VAF 31/182 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); catalogued as COSV67605141; called by muse, mutect2, varscan2
- CDH6 | c.122C>G p.S41C | Missense Mutation (SNP) | VAF 23/194 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.571); catalogued as COSV54071934; called by muse, mutect2, varscan2
- CFAP157 | c.704C>A p.T235N | Missense Mutation (SNP) | VAF 10/115 reads (9%) | SIFT tolerated (0.1); PolyPhen benign (0.041); catalogued as COSV58853426; called by muse, mutect2
- CMYA5 | c.10896G>A p.M3632I | Missense Mutation (SNP) | VAF 21/136 reads (15%) | SIFT tolerated (0.16); PolyPhen benign (0.24); catalogued as COSV71406638; called by muse, mutect2, varscan2
- CRHBP | c.724G>T p.D242Y | Missense Mutation (SNP) | VAF 69/387 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57188937; called by muse, mutect2, varscan2
- CTTNBP2 | c.1196C>T p.P399L | Missense Mutation (SNP) | VAF 97/403 reads (24%) | SIFT tolerated (0.15); PolyPhen benign (0.013); catalogued as COSV50411656; called by muse, mutect2, varscan2
- DYNC1H1 | c.11322G>T p.K3774N | Missense Mutation (SNP) | VAF 27/173 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64138117; called by muse, mutect2, varscan2
- EGFR | c.3554G>T p.G1185V | Missense Mutation (SNP) | VAF 11/89 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.922); catalogued as COSV51809907; called by muse, mutect2, varscan2
- EPB41L3 | c.443A>C p.K148T | Missense Mutation (SNP) | VAF 56/365 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); catalogued as COSV59457192; called by muse, mutect2, varscan2
- FASLG | c.759T>G p.S253R | Missense Mutation (SNP) | VAF 39/262 reads (15%) | SIFT tolerated (0.66); PolyPhen benign (0.009); catalogued as COSV60680281; called by muse, mutect2, varscan2
- GGT5 | c.1465G>A p.G489R | Missense Mutation (SNP) | VAF 29/138 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs763495821, COSV54069750; called by muse, mutect2, varscan2
- GLOD4 | c.563C>T p.A188V (on ENST00000301328 / NM_001366247.1; = p.A173V on NM_016080.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 55/479 reads (11%) | SIFT tolerated (0.67); PolyPhen benign (0.026); catalogued as COSV56753923; called by muse, mutect2, varscan2
- GSG1L | c.968A>C p.Q323P (on ENST00000447459 / NM_001109763.2; = p.Q168P on NM_144675.2) | Missense Mutation (SNP) | VAF 15/122 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.84); catalogued as rs1453805946, COSV66579591; called by muse, varscan2
- HP1BP3 | c.350+1G>C p.X117_splice | Splice Site (SNP) | VAF 50/308 reads (16%) | catalogued as COSV56563151; called by muse, mutect2, varscan2
- HSDL2 | c.671T>C p.I224T | Missense Mutation (SNP) | VAF 21/156 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.873); catalogued as COSV52715497; called by muse, mutect2, varscan2
- HSPG2 | c.505A>T p.I169F | Missense Mutation (SNP) | VAF 26/197 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.069); catalogued as COSV65930424; called by muse, mutect2
- ITIH3 | c.1670T>A p.L557H | Missense Mutation (SNP) | VAF 11/66 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV69649258; called by muse, mutect2, varscan2
- KMT2D | c.3499G>T p.E1167* | Nonsense Mutation (SNP) | VAF 31/192 reads (16%) | catalogued as COSV56452448; called by muse, mutect2, varscan2
- LCN2 | c.287G>A p.C96Y | Missense Mutation (SNP) | VAF 22/150 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs770148758, COSV52981174; called by muse, mutect2, varscan2
- LOX | c.499G>A p.V167M | Missense Mutation (SNP) | VAF 31/196 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.033); catalogued as COSV50238387; called by muse, mutect2, varscan2
- LRRC74A | c.474A>T p.Q158H | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as COSV53610407; called by muse, mutect2, varscan2
- MAGEA11 | c.890T>A p.L297H | Missense Mutation (SNP) | VAF 57/150 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV60756493; called by muse, mutect2, varscan2
- MDGA1 | c.600G>C p.K200N | Missense Mutation (SNP) | VAF 14/99 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV51797282; called by muse, mutect2, varscan2
- MPEG1 | c.661C>T p.L221F | Missense Mutation (SNP) | VAF 15/123 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.301); catalogued as COSV57091835, COSV99915110; called by muse, mutect2, varscan2
- MRPS9 | c.576-1G>C p.X192_splice | Splice Site (SNP) | VAF 18/82 reads (22%) | catalogued as COSV51520154; called by muse, mutect2, varscan2
- MTX1 | c.65G>A p.S22N | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0.011); catalogued as COSV57427024; called by muse, mutect2, varscan2
- NEUROG3 | c.294C>A p.N98K | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.355); catalogued as COSV54343177; called by muse, mutect2, varscan2
- NGLY1 | c.644G>C p.R215T | Missense Mutation (SNP) | VAF 15/101 reads (15%) | SIFT tolerated (0.44); PolyPhen benign (0.003); catalogued as COSV54987385; called by muse, mutect2, varscan2
- NPTX1 | c.617C>A p.T206N | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT tolerated (1); PolyPhen possibly damaging (0.769); catalogued as rs1476912304, COSV60775449; called by muse, mutect2, varscan2
- PIP5K1C | c.1647C>T p.Y549= | Splice Region (SNP) | VAF 17/94 reads (18%) | catalogued as rs1172528048, COSV58953173; called by muse, mutect2, varscan2
- POU3F4 | c.202T>C p.S68P | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT tolerated (0.44); PolyPhen benign (0.006); catalogued as COSV100937242; called by muse, mutect2, varscan2
- SETBP1 | c.1096G>A p.E366K | Missense Mutation (SNP) | VAF 34/191 reads (18%) | SIFT tolerated (0.19); PolyPhen benign (0.052); catalogued as COSV56321385, COSV56325917; called by muse, mutect2, varscan2
- SLC43A3 | c.1060+1G>T p.X354_splice | Splice Site (SNP) | VAF 20/298 reads (7%) | catalogued as COSV61450604; called by muse, mutect2
- SNTG2 | c.530G>T p.S177I | Missense Mutation (SNP) | VAF 52/444 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV57988859; called by muse, mutect2, varscan2
- SSTR2 | c.376C>G p.Q126E | Missense Mutation (SNP) | VAF 29/143 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV59535331; called by muse, mutect2, varscan2
- STK35 | c.854C>T p.S285L | Missense Mutation (SNP) | VAF 7/81 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as COSV55691316; called by muse, mutect2
- TBC1D22A | c.1216C>T p.H406Y | Missense Mutation (SNP) | VAF 18/139 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.943); catalogued as COSV61440645; called by muse, mutect2, varscan2
- TBX5 | c.919C>A p.P307T | Missense Mutation (SNP) | VAF 25/142 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as COSV59862226; called by muse, mutect2, varscan2
- TTN | c.67771A>G p.T22591A (on ENST00000591111; = p.T15167A on NM_003319.4) | Missense Mutation (SNP) | VAF 41/227 reads (18%) | PolyPhen probably damaging (0.994); catalogued as COSV60132601; called by muse, mutect2, varscan2
- UNC93A | c.383A>T p.K128M | Missense Mutation (SNP) | VAF 32/267 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV57809016; called by muse, mutect2, varscan2
- VPS35 | c.718C>G p.Q240E | Missense Mutation (SNP) | VAF 40/235 reads (17%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV54479453; called by muse, mutect2, varscan2
- XPO4 | c.491T>G p.L164W | Missense Mutation (SNP) | VAF 35/215 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV55008972; called by muse, mutect2, varscan2
- ZNF17 | c.1063G>A p.E355K | Missense Mutation (SNP) | VAF 42/236 reads (18%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.559); catalogued as COSV56921681; called by muse, mutect2, varscan2
- ZNF341 | c.2440G>T p.E814* (on ENST00000375200 / NM_001282935.1; = p.E807* on NM_032819.4) | Nonsense Mutation (SNP) | VAF 9/91 reads (10%) | catalogued as rs1320051746, COSV61009357; called by muse, mutect2, varscan2
- DSCAM | c.5067del p.D1690Tfs*11 | Frame Shift Del (DEL) | VAF 16/166 reads (10%) | called by mutect2, pindel, varscan2
- GAPVD1 | c.3556_3560del p.R1186Cfs*5 (on ENST00000394104; = p.R1195Cfs*5 on NM_015635.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 35/288 reads (12%) | called by mutect2, pindel, varscan2
- PEAK1 | c.4173_4189del p.C1391* | Nonsense Mutation (DEL) | VAF 24/233 reads (10%) | called by mutect2, pindel
- RASAL2 | c.2880_2882del p.A961del | In Frame Del (DEL) | VAF 14/104 reads (13%) | called by pindel, varscan2
- SDAD1 | c.1017del p.L339Ffs*12 | Frame Shift Del (DEL) | VAF 15/77 reads (19%) | called by mutect2, pindel, varscan2
- TTC4 | c.446_452del p.C149Sfs*4 | Frame Shift Del (DEL) | VAF 10/94 reads (11%) | called by mutect2, pindel
- BOD1L1 | c.7023C>T p.S2341= | Silent (SNP) | VAF 9/69 reads (13%) | catalogued as rs367990092; called by muse, mutect2, varscan2
- CYYR1 | c.405C>A p.T135= | Silent (SNP) | VAF 21/127 reads (17%) | catalogued as rs750724977, COSV54833502; called by muse, mutect2, varscan2
- DNAH2 | c.4158G>A p.K1386= | Silent (SNP) | VAF 44/241 reads (18%) | catalogued as COSV66720972; called by muse, mutect2, varscan2
- FAM83B | c.243T>C p.D81= | Silent (SNP) | VAF 59/408 reads (14%) | catalogued as rs1165805893, COSV60923148; called by muse, mutect2, varscan2
- FBN3 | c.66C>T p.A22= | Silent (SNP) | VAF 6/26 reads (23%) | catalogued as rs1163864191, COSV54463760; called by muse, mutect2, varscan2
- FUT9 | c.156C>T p.N52= | Silent (SNP) | VAF 34/202 reads (17%) | catalogued as rs534420311, COSV56149270; called by muse, mutect2, varscan2
- HELB | c.3075A>G p.V1025= | Silent (SNP) | VAF 30/164 reads (18%) | catalogued as rs1451669279, COSV56074209; called by muse, mutect2, varscan2
- MED13 | c.156C>T p.P52= | Silent (SNP) | VAF 69/373 reads (18%) | catalogued as rs751796433, COSV67264287; called by muse, mutect2, varscan2
- NPHP4 | c.1992G>A p.K664= | Silent (SNP) | VAF 20/159 reads (13%) | catalogued as COSV65394731, COSV65395573; called by muse, mutect2, varscan2
- RBP3 | c.1026G>A p.T342= | Silent (SNP) | VAF 18/104 reads (17%) | catalogued as rs781847771; called by muse, mutect2, varscan2
- TIAM2 | c.985C>T p.L329= | Silent (SNP) | VAF 17/110 reads (15%) | catalogued as COSV59696325; called by muse, mutect2, varscan2
- TNXB | c.8901C>A p.T2967= (on ENST00000647633; = p.T2720= on NM_019105.8 and 1 other RefSeq transcript) | Silent (SNP) | VAF 10/82 reads (12%) | catalogued as COSV64480903; called by muse, mutect2
- AFDN | chr6:167826244 T>A | 5'Flank (SNP) | VAF 16/244 reads (7%) | called by muse, mutect2
- AL353804.6 | chrX:73826909 T>C | 3'Flank (SNP) | VAF 46/121 reads (38%) | catalogued as rs1473139669; called by muse, mutect2, varscan2
- AL353804.6 | chrX:73826910 C>T | 3'Flank (SNP) | VAF 48/122 reads (39%) | catalogued as rs1183704450; called by muse, mutect2, varscan2
- AP000769.3 | chr11:65504080 A>G | 5'Flank (SNP) | VAF 7/55 reads (13%) | catalogued as rs747972880; called by muse, mutect2, varscan2
- CCDC144B | n.466C>A | RNA (SNP) | VAF 30/552 reads (5%) | called by muse, mutect2
- CCDC144B | n.465C>A | RNA (SNP) | VAF 29/547 reads (5%) | catalogued as rs371860610; called by muse, mutect2
- FAM27E5 | n.416G>T | RNA (SNP) | VAF 17/123 reads (14%) | called by muse, mutect2, varscan2
- LINC00518 | n.1081A>C | RNA (SNP) | VAF 60/419 reads (14%) | called by muse, mutect2, varscan2
- LINC01098 | n.744T>A | RNA (SNP) | VAF 14/361 reads (4%) | called by muse, mutect2
- SEC14L1 | c.-240+203G>C | Intron (SNP) | VAF 39/197 reads (20%) | catalogued as COSV100811351; called by muse, mutect2, varscan2
